Somatic mutation profile of tumor specimen TCGA-S9-A7R7-01A (aliquot TCGA-S9-A7R7-01A-11D-A34J-08) from TCGA case TCGA-S9-A7R7, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 27.7 years (10,108 days).
Specimen TCGA-S9-A7R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65cfbdec-06f1-4685-a74f-a96427884c81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7R7-10A (Blood Derived Normal), aliquot TCGA-S9-A7R7-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ad0034c-4893-4197-bf38-b1ccc96317c2

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99285213; called by muse, mutect2, varscan2
- ATRX | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 100/196 reads (51%) | catalogued as rs1311466929, COSV64873935; called by muse, mutect2, varscan2
- CCM2L | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs61748626, COSV99395030; called by muse, mutect2, varscan2
- GBP5 | c.1336T>C p.Y446H | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as COSV100600006; called by muse, mutect2, varscan2
- MNDA | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs767300186, COSV100933446, COSV63742115; called by muse, mutect2, varscan2
- OCA2 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs367553582; called by muse, mutect2, varscan2
- OR4C46 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 69/244 reads (28%) | catalogued as rs775929413, COSV100060502; called by muse, mutect2, varscan2
- PGAP1 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100698076; called by muse, mutect2, varscan2
- SLC13A1 | c.1350+2T>A p.X450_splice | Splice Site (SNP) | VAF 47/153 reads (31%) | catalogued as COSV99520615; called by muse, mutect2, varscan2
- TP53 | c.833del p.P278Lfs*67 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as CM961376, COSV52661225, COSV52665769, COSV52678063; called by mutect2, pindel, varscan2
- USP20 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345756745, COSV100204139; called by muse, mutect2, varscan2
- USP6 | c.2072G>A p.C691Y | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100003466; called by muse, mutect2, varscan2
- UTRN | c.4754C>T p.S1585F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV62337735; called by muse, mutect2, varscan2
- BCOR | c.1618dup p.R540Pfs*17 | Frame Shift Ins (INS) | VAF 32/71 reads (45%) | called by mutect2, pindel, varscan2
- MYT1 | c.14del p.N5Mfs*75 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | called by mutect2, pindel, varscan2
- OSBPL10 | c.1516del p.R506Afs*21 | Frame Shift Del (DEL) | VAF 33/130 reads (25%) | called by mutect2, pindel, varscan2
- ST8SIA1 | c.335_340del p.L112_Y113del | In Frame Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- CAMKV | c.279G>A p.K93= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV99615283; called by muse, mutect2, varscan2
- MAP6 | c.1674T>A p.S558= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV100496541; called by muse, mutect2, varscan2
- TULP1 | c.1530G>A p.A510= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs776991257, COSV57694356; called by muse, mutect2, varscan2
- ZC2HC1C | c.1092C>T p.S364= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs778156784, COSV99472836; called by muse, mutect2, varscan2
